Gene-level copy-number profile of tumor specimen TCGA-GN-A4U7-06A from TCGA case TCGA-GN-A4U7, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.4 years (20,606 days).
Specimen TCGA-GN-A4U7-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.72a2f27c-fbf2-4847-b437-b432040fff3e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GN-A4U7-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8c8cbf68-66b8-4a04-80cd-273fa56abb62

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,754; copy number 2: 43,914; copy number 3: 7,433; copy number 4: 289; copy number 6: 316; copy number 7: 46; copy number 8: 66.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GN-A4U7-06A-21D-A32M-01): tumor purity 0.9, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 428 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:67,452,406–70,436,584, 108 genes, copy number 6 (broad region; genes not listed).
- chr11:70,477,277–70,604,859, 2 genes, copy number 6: AP001271.1, AP001271.2.
- chr11:79,966,805–91,872,086, 206 genes, copy number 6 (broad region; genes not listed).
- chr11:94,128,841–100,358,885, 66 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr11:102,295,060–104,252,651, 46 genes, copy number 7: AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1.

Autosomal genes at a single copy (total copy number 1): 7,754. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
